Gene-level copy-number profile of tumor specimen AP-WTXJ-Q7 from APOLLO case AP-WTXJ, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-WTXJ-Q7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 309f3be7-f565-4b0a-a8ff-fd0ed2656aba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-WTXJ-TG (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,757 have no estimate.
https://portal.gdc.cancer.gov/files/7f8311e8-7caa-4885-8922-e97bdda4d2b0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 549; copy number 1: 447; copy number 2: 4,628; copy number 3: 24,073; copy number 4: 17,574; copy number 5: 8,752; copy number 6: 2,278; copy number 7: 282; copy number 8: 67; copy number 9: 29; copy number 10: 16; copy number 11: 29; copy number 12: 55; copy number 13: 20; copy number 14: 7; copy number 17: 30; copy number 21: 3; copy number 22: 8; copy number 23: 12; copy number 27: 5; copy number 43: 2.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr8:8,086,022–8,086,765, 1 gene: AC105233.2.
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–2): AL513422.1.
- chr9:42,196,333–43,045,120, 27 genes: AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr14:18,692,032–18,909,673, 6 genes: RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7.
- chr15:21,927,657–21,946,641, 1 gene: NF1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 565 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,916,157–47,076,137, 3 genes, copy number 8 (within-gene range 3–8): TTC7A, AC093732.2, AC093732.1.
- chr3:148,695,994–151,080,726, 67 genes, copy number 7 (broad region; genes not listed).
- chr3:167,478,684–172,523,475, 92 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:176,415,439–178,937,352, 28 genes, copy number 7: LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1.
- chr6:11,173,452–11,382,348, 3 genes, copy number 7: AL139807.1, NEDD9, AL022098.1.
- chr7:104,738,597–104,804,107, 1 gene, copy number 21 (within-gene range 3–21): LHFPL3-AS1.
- chr7:104,894,628–106,908,980, 38 genes, copy number 7–22 (within-gene range 3–22): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG.
- chr7:115,503,367–121,419,845, 80 genes, copy number 10–27 (broad region; genes not listed).
- chr9:102,922,574–103,325,034, 4 genes, copy number 10: AL365396.1, CYLC2, AL589823.1, LINC01492.
- chr14:34,981,957–38,371,338, 73 genes, copy number 8–13 (within-gene range 3–16) (broad region; genes not listed).
- chr14:41,514,972–42,268,586, 7 genes, copy number 9–11: AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1.
- chr14:71,932,429–72,566,530, 1 gene, copy number 9 (within-gene range 3–9): RGS6.
- chr14:72,515,407–73,123,899, 15 genes, copy number 9: AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA, DCAF4, AC007160.1, AL442663.4, AL442663.1, ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2.
- chr15:21,951,242–21,951,323, 1 gene, copy number 7: MIR5701-3.
- chr16:32,356,981–32,380,049, 2 genes, copy number 43: AC133548.1, ACTR3BP3.
- chr16:32,475,051–32,478,250, 1 gene, copy number 7: ABCD1P3.
- chr16:32,869,985–32,873,128, 1 gene, copy number 7: BCAP31P2.
- chr20:53,875,252–54,269,542, 7 genes, copy number 7: SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.
- chr21:25,734,570–26,471,698, 10 genes, copy number 8 (within-gene range 4–8): GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1.
- chr21:34,513,142–36,004,667, 9 genes, copy number 7 (within-gene range 6–7): RCAN1, CLIC6, LINC00160, LINC01426, RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1.
- chr21:38,121,451–39,183,488, 24 genes, copy number 7: DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1.
- chr21:39,216,624–39,219,805, 2 genes, copy number 7 (within-gene range 6–7): TIMM9P2, BRWD1-IT1.
- chr21:41,141,493–44,242,081, 94 genes, copy number 7–8 (broad region; genes not listed).
- chr21:46,690,764–46,691,226, 1 gene, copy number 11: RPL23AP4.
- chr22:18,733,914–18,757,906, 1 gene, copy number 7: FAM230E.

Autosomal genes at a single copy (total copy number 1): 447. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
